Somatic mutation profile of tumor specimen TARGET-20-PARBIU-04A (aliquot TARGET-20-PARBIU-04A-01D) from TARGET case TARGET-20-PARBIU, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 16.0 years (5,830 days).
Specimen TARGET-20-PARBIU-04A: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b405f8c0-7215-4d5d-9337-82fbe5872341.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARBIU-14A (Bone Marrow Normal), aliquot TARGET-20-PARBIU-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9e00bc96-977a-4aac-a19f-7b7201b48365

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Frame Shift Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PPP1R14B | c.406C>T p.R136W | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as COSV58588123; called by muse, mutect2, varscan2
- SETD2 | c.4409C>T p.P1470L | Missense Mutation (SNP) | VAF 132/279 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57432503; called by muse, mutect2, varscan2
- SETD2 | c.6941del p.Q2314Rfs*39 | Frame Shift Del (DEL) | VAF 92/259 reads (36%) | called by mutect2, pindel, varscan2
- KMT5B | c.*636del | 3'UTR (DEL) | VAF 146/356 reads (41%) | called by mutect2, pindel, varscan2
